Somatic mutation profile of tumor specimen TCGA-X7-A8DI-01A (aliquot TCGA-X7-A8DI-01A-11D-A423-09) from TCGA case TCGA-X7-A8DI, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 57.7 years (21,086 days).
Specimen TCGA-X7-A8DI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3366bbd2-1217-4eb0-b7ce-70195bbc2d61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8DI-10A (Blood Derived Normal), aliquot TCGA-X7-A8DI-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1445faf4-9c3f-43c9-aa4a-c357b1a9404c

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 39/603 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- CCNL1 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV55817443; called by muse, mutect2
- DIP2B | c.3046A>G p.T1016A | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV56589532; called by muse, mutect2
- CDH20 | c.1475C>A p.P492Q | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPSM2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MSL2 | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.009); called by muse, mutect2
- SLC25A25 | c.1091G>A p.W364* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- ZNF579 | c.1356C>A p.R452= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
